TCGA case TCGA-04-1364 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/80f85c54-e12f-4afa-8fa5-5f3e083b6f95

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 1,024 days (2.8 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 61.0 years (22,294 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 35 days; Days to treatment end: 188 days; Number of cycles: 7; Treatment dose: 5 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 35 days; Days to treatment end: 188 days; Number of cycles: 7; Treatment dose: 2,408 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 35 days; Days to treatment end: 188 days; Number of cycles: 7; Treatment dose: 235 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 279 days; Days to treatment end: 310 days; Number of cycles: 2; Treatment dose: 20 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Recurrent Disease; Days to treatment start: 279 days; Days to treatment end: 310 days; Number of cycles: 2; Treatment dose: 198 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Altretamine; Initial disease status: Recurrent Disease; Days to treatment start: 341 days; Days to treatment end: 370 days (1.0 years); Number of cycles: 2; Treatment dose: 1,400 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 401 days (1.1 years); Days to treatment end: 462 days (1.3 years); Number of cycles: 2; Treatment dose: 240 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Recurrent Disease; Days to treatment start: 401 days (1.1 years); Days to treatment end: 462 days (1.3 years); Number of cycles: 2; Treatment dose: 6,400 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Recurrent Disease; Days to treatment start: 462 days (1.3 years); Days to treatment end: 584 days (1.6 years); Number of cycles: 5; Treatment dose: 10,500 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 615 days (1.7 years); Days to treatment end: 827 days (2.3 years); Number of cycles: 14; Treatment dose: 1,860 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin; Initial disease status: Recurrent Disease; Days to treatment start: 615 days (1.7 years); Days to treatment end: 827 days (2.3 years); Number of cycles: 14; Treatment dose: 7,000 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Innate Immunostimulator rBBX-01; Initial disease status: Recurrent Disease; Days to treatment start: 857 days (2.3 years); Days to treatment end: 857 days (2.3 years); Number of cycles: 1; Treatment dose: 9 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 919 days (2.5 years); Days to treatment end: 949 days (2.6 years); Number of cycles: 2; Treatment dose: 5 AUC.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 919 days (2.5 years); Days to treatment end: 949 days (2.6 years); Number of cycles: 2; Treatment dose: 260 mg.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 61.8 years (22,582 days); Days to diagnosis: 288 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 288 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 288 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,024 days (2.8 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1364-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-04-1364-01A-01-TS1: Section location: Top; Percent tumor cells: 93; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 5.
  Slide TCGA-04-1364-01A-01-BS1: Section location: Bottom; Percent tumor cells: 93; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 5.
- Sample TCGA-04-1364-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 5: Pharmaceutical therapy drug name: 5F4 Leucovorin.
- Drug treatment 6: Pharmaceutical therapy drug name: RBBX 01.
- Drug treatment 8: Pharmaceutical therapy drug name: Hexalen.
- Drug treatment 10: Pharmaceutical therapy drug name: Navelbine.
- Follow-up form: Treatment outcome first course: Progressive Disease; Tumor status: With tumor.

GDC annotations on this case (curator notes; quoted as recorded):
- General: This subject was duplicated by TCGA-24-0981; 0981 was redacted and this one retained.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,024 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,024 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 288 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-04-1364-01): tumor purity 0.9, ploidy 5.58, whole-genome doublings 2 (call status: legacy_call).
